Gene-level copy-number profile of tumor specimen TCGA-18-3406-01A from TCGA case TCGA-18-3406, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.0 years (24,477 days).
Specimen TCGA-18-3406-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0f960732-d006-45f6-81d4-6ae8e659c75d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-3406-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6afc0e8b-eb6c-4d5a-9c00-3c6ca4472faa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 113; copy number 1: 15,275; copy number 2: 39,445; copy number 3: 3,338; copy number 4: 1,029; copy number 5: 349; copy number 6: 163; copy number 7: 34; copy number 8: 5; copy number 9: 27; copy number 10: 32; copy number 12: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-3406-01A-01D-0978-01): tumor purity 0.48, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,892,188–31,381,490, 85 genes (broad region; genes not listed).
- chr13:94,154,193–95,019,336, 14 genes: GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 588 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:204,306,842–205,620,162, 7 genes, copy number 6 (within-gene range 1–6): DSTNP5, AC106901.1, AC016903.1, AC016903.2, PARD3B, AC007736.1, AC008171.1.
- chr3:96,244,732–96,814,407, 10 genes, copy number 6: AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1.
- chr6:30,184,455–33,298,942, 264 genes, copy number 5–10 (broad region; genes not listed).
- chr7:85,381,118–85,636,344, 3 genes, copy number 10: DYNLL1P7, LINC00972, AC092013.1.
- chr7:91,030,149–94,834,447, 69 genes, copy number 5 (broad region; genes not listed).
- chr12:96,422,326–96,485,442, 1 gene, copy number 8 (within-gene range 2–8): AC007513.1.
- chr12:96,489,571–97,276,209, 9 genes, copy number 8–12: CFAP54, EEF1A1P33, NEDD1, Y_RNA, AC007656.2, AC007656.1, AC007656.3, AC007656.4, LINC02409.
- chr19:54,155,161–55,778,900, 146 genes, copy number 6 (broad region; genes not listed).
- chr19:57,819,719–58,605,223, 79 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,252. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
